Somatic mutation profile of tumor specimen TCGA-78-7147-01A (aliquot TCGA-78-7147-01A-11D-2036-08) from TCGA case TCGA-78-7147, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 67.9 years (24,809 days).
Specimen TCGA-78-7147-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe6029e2-872b-44b4-a22b-1a9fc0e33739.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7147-10A (Blood Derived Normal), aliquot TCGA-78-7147-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1efa2b4-7be6-44db-8eb1-52acf869b6e0

The open-access MAF lists 379 somatic variants for this specimen: 275 protein-altering or splice-affecting, 98 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 98, Nonsense Mutation 19, Frame Shift Del 11, Frame Shift Ins 5, Splice Region 3, 3'Flank 3, Splice Site 2, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11B1 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563867899, CM103705, COSV52828614; ClinVar: pathogenic; called by muse, mutect2
- EGFR | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 99/164 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121913444, COSV51766344, COSV51766618; ClinVar: pathogenic / likely pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.708C>A p.Y236* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | hotspot (GDC flag); catalogued as CD951866, COSV52713084, COSV52728511, COSV53025106, COSV53864205; called by muse, mutect2, varscan2
- ADAMTS20 | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV67130846; called by muse, mutect2, varscan2
- ADGRB3 | c.4155G>C p.K1385N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as COSV53243163, COSV99484609; called by muse, mutect2, varscan2
- ADNP2 | c.893A>G p.Q298R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV51538500; called by muse, mutect2, varscan2
- AEBP1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV56257386; called by muse, mutect2
- AGAP3 | c.172G>C p.E58Q (on ENST00000622464; = p.E94Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.179); catalogued as COSV52543956; called by muse, mutect2, varscan2
- AGPAT4 | c.791C>G p.P264R | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57245617; called by muse, mutect2, varscan2
- AGTR2 | c.1036A>G p.S346G | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV64156440; called by muse, mutect2, varscan2
- ANGEL1 | c.1865A>G p.Y622C | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); catalogued as rs1338748320, COSV51873106; called by muse, mutect2, varscan2
- ANK2 | c.8191G>A p.G2731S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV52159460; called by muse, mutect2, varscan2
- ANKRD30A | c.2037C>A p.D679E (on ENST00000611781; = p.D623E on NM_052997.2) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.785); catalogued as COSV64609473; called by muse, mutect2, varscan2
- ARHGEF11 | c.3401G>A p.G1134E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.719); catalogued as COSV59354222, COSV59355129; called by mutect2, varscan2
- ARHGEF28 | c.1749G>T p.E583D | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV55255327; called by muse, mutect2, varscan2
- ATXN3L | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV66075646; called by muse, mutect2, varscan2
- BAZ1A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62410079; called by muse, mutect2, varscan2
- BCAM | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV54302101; called by muse, varscan2
- BLK | c.665G>C p.R222P | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52051124, COSV52051599; called by muse, mutect2, varscan2
- BSX | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104420659, COSV58005500; called by muse, mutect2, varscan2
- BTBD10 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53398969; called by muse, mutect2, varscan2
- CACNA1D | c.1684C>T p.L562F (on ENST00000350061 / NM_001128840.3; = p.L582F on NM_000720.4) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.288); catalogued as COSV55445915; called by muse, mutect2, varscan2
- CACNA1F | c.4111C>A p.Q1371K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59904315; called by muse, mutect2, varscan2
- CACNA2D1 | c.646C>G p.R216G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100667570, COSV62373354; called by muse, mutect2, varscan2
- CACNG6 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs534917640; called by muse, mutect2
- CADM2 | c.812C>A p.P271H (on ENST00000407528 / NM_001167674.2; = p.P273H on NM_153184.4) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV101059104, COSV67372106; called by muse, mutect2, varscan2
- CASP2 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.859); catalogued as COSV60082098; called by muse, mutect2, varscan2
- CCNJL | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs747988573, COSV57444580; called by muse, mutect2, varscan2
- CDH18 | c.1382C>A p.S461* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV56919589; called by muse, mutect2, varscan2
- CDK5R1 | c.512C>G p.P171R | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55578637; called by muse, mutect2
- CELSR1 | c.3778G>A p.V1260M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53089423; called by muse, mutect2, varscan2
- CENPF | c.5281G>C p.D1761H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV65274759; called by muse, mutect2, varscan2
- CHRNA4 | c.628G>T p.V210F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); catalogued as COSV64719359; called by muse, mutect2, varscan2
- CHRNA7 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs568931594, COSV60974599; called by mutect2, varscan2
- CMTM5 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV59305698; called by muse, mutect2, varscan2
- CSF1R | c.413T>A p.V138D | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV53834280; called by muse, mutect2, varscan2
- CX3CR1 | c.758T>A p.L253Q | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64193772; called by muse, mutect2, varscan2
- CYYR1 | c.187A>T p.I63F | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV54831522; called by muse, mutect2
- DCAF12L2 | c.1231C>A p.L411I | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs762151692, COSV63581498; called by muse, mutect2, varscan2
- DEPDC5 | c.676T>A p.Y226N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56696760; called by muse, mutect2, varscan2
- DGKD | c.2094T>G p.S698R (on ENST00000264057 / NM_152879.3; = p.S654R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV51044582, COSV51050986; called by muse, mutect2, varscan2
- DHX40 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52067362; called by muse, varscan2
- DIPK2B | c.798C>A p.D266E | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101211727, COSV67641122; called by muse, mutect2, varscan2
- DLGAP2 | c.1298T>C p.M433T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV70097778; called by muse, mutect2
- DLGAP3 | c.1801C>G p.P601A | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.057); catalogued as COSV52393769; called by muse, mutect2, varscan2
- DMD | c.7411G>C p.A2471P | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); catalogued as COSV58908190; called by muse, mutect2, varscan2
- DNAH5 | c.13055G>T p.R4352L | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54222229; called by muse, mutect2, varscan2
- DNAI2 | c.67C>A p.R23S | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV56757157, COSV56758481; called by muse, mutect2, varscan2
- DRD5 | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV58577863; called by muse, mutect2, varscan2
- DSCAML1 | c.2133G>T p.M711I (on ENST00000321322; = p.M651I on NM_020693.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.205); catalogued as COSV58389773; called by muse, mutect2, varscan2
- DYTN | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101123999; called by muse, mutect2, varscan2
- EGFR | c.1159C>A p.L387M | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.981); catalogued as COSV51797369, COSV51858303; called by muse, mutect2, varscan2
- EHBP1 | c.2362G>A p.D788N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV50419588; called by muse, mutect2, varscan2
- EIF2AK1 | c.126T>A p.D42E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV52238859; called by muse, mutect2
- EIF4E1B | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV53780138; called by muse, mutect2, varscan2
- EIF4E1B | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV53780141, COSV53780425; called by muse, mutect2, varscan2
- EMSY | c.1548C>G p.S516R | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58259872; called by muse, mutect2, varscan2
- ESX1 | c.116G>T p.R39M | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as COSV65424271; called by muse, mutect2, varscan2
- FAM47C | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.168); catalogued as COSV63726343; called by muse, mutect2, varscan2
- FBLN2 | c.2486A>G p.N829S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55484041; called by muse, mutect2
- FBXO21 | c.1455G>C p.E485D (on ENST00000330622 / NM_033624.3; = p.E478D on NM_015002.3) | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV57972672; called by muse, mutect2, varscan2
- FGD6 | c.1079A>T p.K360I | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV59692893; called by muse, mutect2, varscan2
- FGFR1 | c.8G>T p.S3I | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV58333765; called by muse, mutect2, varscan2
- FHDC1 | c.2968A>T p.R990W | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52599598; called by muse, mutect2, varscan2
- FKBP6 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs782794976, COSV52719619; called by muse, mutect2
- FLG | c.6662G>T p.R2221I | Missense Mutation (SNP) | VAF 142/354 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV64241398; called by muse, mutect2, varscan2
- FLNC | c.6635A>T p.Q2212L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV57955372; called by muse, mutect2
- FLT3 | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV54052492; called by muse, mutect2, varscan2
- FRMD7 | c.1913A>G p.D638G | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53745972; called by muse, mutect2, varscan2
- FRS2 | c.631A>G p.S211G | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54725506; called by muse, mutect2, varscan2
- FSTL5 | c.1108C>A p.P370T | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60193740; called by muse, mutect2, varscan2
- FUNDC2 | c.495G>T p.V165= | Splice Region (SNP) | VAF 31/129 reads (24%) | catalogued as COSV65670877, COSV65671350; called by muse, mutect2, varscan2
- GABRA6 | c.1223C>G p.S408W | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as COSV50878114, COSV50880554; called by muse, mutect2, varscan2
- GALNT5 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV52037610; called by muse, mutect2, varscan2
- GATA4 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 19/119 reads (16%) | catalogued as COSV58733310; called by muse, mutect2, varscan2
- GBA3 | c.854G>C p.R285T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72438091, COSV72438249; called by muse, mutect2, varscan2
- GCLC | c.153G>T p.L51F (on ENST00000643939; = p.L55F on NM_001498.4) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV57595245; called by muse, mutect2
- GDI1 | c.1319A>C p.D440A | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV50131100; called by muse, mutect2, varscan2
- GFPT1 | c.1273A>T p.R425* (on ENST00000357308 / NM_001244710.2; = p.R407* on NM_002056.4) | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV61947850; called by muse, mutect2
- GLRA3 | c.1157A>T p.Y386F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV56861246; called by muse, mutect2, varscan2
- GPATCH8 | c.1341G>T p.K447N | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV59194690; called by muse, mutect2, varscan2
- GPR119 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 90/181 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.745); catalogued as COSV52275618; called by muse, mutect2, varscan2
- GPR20 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66684391; called by muse, mutect2, varscan2
- GPRASP2 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV59991164; called by muse, mutect2, varscan2
- GRIN2A | c.1534C>T p.L512F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV58031187; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782101818; called by muse, mutect2, varscan2
- H2BC4 | c.213T>G p.F71L | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); catalogued as COSV58415779; called by muse, mutect2, varscan2
- H3C6 | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV64519558; called by muse, mutect2, varscan2
- HACE1 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV53502066, COSV53505656; called by muse, mutect2, varscan2
- HELZ | c.4622A>G p.Q1541R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV62378290; called by muse, mutect2, varscan2
- HGFAC | c.1270G>C p.A424P | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755798844, COSV66976846; called by muse, mutect2, varscan2
- HPX | c.70A>T p.T24S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56419231; called by muse, mutect2, varscan2
- HSPA8 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.315); catalogued as COSV57083834; called by muse, mutect2, varscan2
- HUWE1 | c.11062G>T p.E3688* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV53344317; called by muse, mutect2, varscan2
- IGF2BP1 | c.1602G>C p.Q534H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV51731005; called by muse, mutect2, varscan2
- IGF2R | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.607); catalogued as rs756743378, COSV63628780; called by muse, mutect2, varscan2
- IL10RA | c.1193A>T p.Q398L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV57140450; called by muse, mutect2, varscan2
- IL9R | c.864C>A p.Y288* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as COSV54899706; called by muse, mutect2
- INHBE | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.206); catalogued as COSV56987954; called by muse, varscan2
- INSC | c.1480C>A p.L494M | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65410335; called by muse, mutect2, varscan2
- INSM1 | c.1511T>C p.V504A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV59604741; called by muse, mutect2, varscan2
- IPO9 | c.2201A>G p.E734G | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV64233600; called by muse, mutect2, varscan2
- IRGC | c.1346A>T p.K449M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54984011; called by muse, mutect2, varscan2
- ITGA2 | c.1715T>A p.V572E | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56859292; called by muse, mutect2, varscan2
- ITGA4 | c.2066T>C p.L689S | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67897150; called by muse, mutect2, varscan2
- ITGB3 | c.1769C>G p.T590S | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV71383958; called by muse, mutect2, varscan2
- KCNA6 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV54974658, COSV54975066; called by muse, mutect2, varscan2
- KCNH6 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs560196120, COSV59000890; called by muse, mutect2, varscan2
- KIAA0408 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV100847103; called by muse, mutect2, varscan2
- KLF17 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV64856261; called by muse, mutect2, varscan2
- KRTAP1-3 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV60336037; called by muse, mutect2, varscan2
- LAMC1 | c.2008G>C p.D670H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51140403; called by muse, mutect2
- LARP1 | c.2699A>T p.E900V (on ENST00000518297 / NM_033551.3; = p.E823V on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60426848; called by muse, varscan2
- LGR6 | c.1714G>A p.V572M (on ENST00000367278 / NM_001017403.1; = p.V520M on NM_021636.3) | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as rs763743707, COSV55154505; called by muse, mutect2, varscan2
- LILRB2 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs774001588, COSV58745048; called by muse, mutect2, varscan2
- LMO4 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV65170255; called by muse, mutect2, varscan2
- LONRF3 | c.1217C>T p.P406L (on ENST00000371628 / NM_001031855.3; = p.P365L on NM_024778.5) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59151927; called by muse, mutect2, varscan2
- LRRC7 | c.1741C>T p.P581S (on ENST00000651989 / NM_001370785.2; = p.P548S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV50450594; called by muse, mutect2, varscan2
- LRRC75B | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as COSV50640116; called by muse, mutect2, varscan2
- MAGEB10 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63311163; called by muse, mutect2, varscan2
- MAGEB6 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as COSV66871888, COSV66872013; called by muse, mutect2, varscan2
- MED12 | c.3357C>A p.V1119= | Splice Region (SNP) | VAF 19/55 reads (35%) | catalogued as COSV61338939; called by muse, mutect2, varscan2
- MEGF8 | c.2329G>A p.E777K (on ENST00000251268 / NM_001271938.2; = p.E710K on NM_001410.3) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV52083630; called by muse, mutect2, varscan2
- MORC3 | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as COSV68688326; called by muse, mutect2, varscan2
- MPP1 | c.678-2A>G p.X226_splice | Splice Site (SNP) | VAF 17/31 reads (55%) | catalogued as COSV65728190; called by muse, mutect2, varscan2
- MPPE1 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as COSV57882398; called by muse, mutect2, varscan2
- MUC16 | c.22090C>G p.H7364D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV67463327; called by muse, mutect2, varscan2
- MUC17 | c.9784T>A p.S3262T | Missense Mutation (SNP) | VAF 136/411 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as rs200198579, COSV100075462; called by muse, mutect2, varscan2
- MUC17 | c.11898A>G p.I3966M | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV60287602; called by muse, mutect2
- N4BP2 | c.1015A>T p.K339* | Nonsense Mutation (SNP) | VAF 36/72 reads (50%) | catalogued as COSV54701544; called by muse, mutect2, varscan2
- NEDD9 | c.1507A>T p.S503C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as COSV65220829; called by muse, mutect2, varscan2
- NES | c.4610G>A p.G1537D | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV63960951; called by muse, mutect2, varscan2
- NFATC4 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV51601502; called by muse, mutect2, varscan2
- NFRKB | c.1655G>A p.G552D (on ENST00000446488 / NM_001143835.2; = p.G577D on NM_006165.3) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58757813; called by muse, mutect2, varscan2
- NPAP1 | c.2354C>A p.S785Y | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.35); catalogued as COSV61504768, COSV61506638; called by muse, mutect2, varscan2
- NPR3 | c.1079G>C p.G360A | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.6); PolyPhen probably damaging (1); catalogued as COSV54087320; called by muse, mutect2
- NRG3 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.187); catalogued as COSV64559462; called by muse, mutect2, varscan2
- NUP153 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs1362700903, COSV50449183; called by muse, mutect2, varscan2
- NUP205 | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.24); catalogued as COSV53658549; called by muse, mutect2, varscan2
- ODF3L2 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV52745690; called by muse, mutect2, varscan2
- OPN1LW | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.565); catalogued as COSV64049370; called by muse, varscan2
- OR10AG1 | c.445G>C p.G149R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV56632774; called by muse, mutect2, varscan2
- OR10Z1 | c.179A>T p.Y60F | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63524727; called by muse, mutect2, varscan2
- OR2AK2 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV63552452; called by muse, mutect2, varscan2
- OR2J2 | c.601A>G p.M201V | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs369758145; called by muse, mutect2
- OR2T2 | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV61618036; called by muse, mutect2, varscan2
- OR4A16 | c.347T>A p.M116K | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV59042967, COSV59044793; called by muse, mutect2, varscan2
- OR4A47 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs906033872, COSV71444917; called by muse, mutect2, varscan2
- OR4C6 | c.537G>T p.L179F | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.162); catalogued as COSV58603749; called by muse, mutect2, varscan2
- OR4M1 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV60061142; called by muse, mutect2
- OR52B2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV73209339; called by muse, mutect2, varscan2
- OR6F1 | c.830T>A p.L277Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57467668; called by muse, mutect2, varscan2
- OR6K6 | c.956T>A p.L319Q (on ENST00000368144; = p.L295Q on NM_001005184.1) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63744101; called by muse, mutect2, varscan2
- OR8B8 | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60144464; called by muse, mutect2, varscan2
- OR8K3 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); catalogued as COSV57131466; called by muse, mutect2, varscan2
- OR8U1 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs1201903844, COSV100164168; called by muse, mutect2
- PCDHA5 | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.581); catalogued as COSV65352037; called by muse, mutect2, varscan2
- PCDHB16 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV53361819; called by muse, mutect2, varscan2
- PCDHB2 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.117); catalogued as rs782157911, COSV50571490; called by muse, mutect2, varscan2
- PCDHB7 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV50765628; called by muse, mutect2, varscan2
- PCDHGA2 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.055); catalogued as COSV53941650; called by muse, mutect2, varscan2
- PCSK1 | c.2039C>A p.P680Q | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV60735006; called by muse, mutect2, varscan2
- PDIA4 | c.1235G>T p.R412M (on ENST00000286091 / NM_001371244.1; = p.R411M on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV53724614; called by muse, mutect2, varscan2
- PGGT1B | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV56973805; called by muse, mutect2, varscan2
- PHF1 | c.1475C>T p.S492L (on ENST00000374516 / NM_024165.3; = p.R457* on NM_002636.5) | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV53380960; called by muse, mutect2, varscan2
- PHF21A | c.1397C>T p.T466I | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.139); catalogued as rs371948562; called by muse, mutect2
- PHYKPL | c.1055T>C p.I352T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV57424114; called by muse, mutect2, varscan2
- PKD1L1 | c.7908G>T p.M2636I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.113); catalogued as COSV51842278; called by muse, mutect2, varscan2
- POLR3B | c.774G>T p.E258D | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV57278751; called by muse, mutect2, varscan2
- PRAMEF12 | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV63215221; called by muse, mutect2, varscan2
- PRDM14 | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52572077; called by muse, mutect2, varscan2
- PRDM2 | c.4842G>C p.R1614S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV52446055; called by muse, mutect2, varscan2
- PRDM8 | c.453G>T p.G151= | Splice Region (SNP) | VAF 26/83 reads (31%) | catalogued as COSV60203451; called by muse, mutect2, varscan2
- PRDM9 | c.2255A>T p.E752V | Missense Mutation (SNP) | VAF 115/236 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV57005869; called by muse, varscan2
- PREX1 | c.861G>T p.Q287H | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64251363; called by muse, mutect2, varscan2
- PRMT6 | c.708C>G p.I236M | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as COSV63655466; called by muse, mutect2, varscan2
- PTAFR | c.810del p.I271Lfs*18 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | catalogued as COSV59536484; called by mutect2, pindel, varscan2
- PTCHD3 | c.1833G>C p.L611F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.085); catalogued as COSV71256746; called by muse, mutect2, varscan2
- PTPRN2 | c.1865C>A p.S622Y | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV67035912; called by muse, mutect2, varscan2
- PXDNL | c.1783C>G p.L595V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.773); catalogued as COSV62486637; called by muse, mutect2, varscan2
- PYHIN1 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1237857684, COSV63722320; called by muse, mutect2, varscan2
- RAB9B | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV54587506; called by muse, mutect2, varscan2
- RANBP6 | c.1789T>G p.S597A | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV52389237; called by muse, varscan2
- REST | c.1460A>T p.Q487L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV58360496; called by muse, mutect2, varscan2
- RIPOR2 | c.795C>G p.I265M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52420923; called by muse, mutect2, varscan2
- RNF180 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56961703; called by muse, mutect2, varscan2
- RPL4 | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV57179636; called by muse, mutect2, varscan2
- RTL8B | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.95); catalogued as COSV66954276; called by muse, mutect2, varscan2
- RYR2 | c.4421G>T p.G1474V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV63668461, COSV63683480; called by muse, mutect2, varscan2
- RYR2 | c.4781T>G p.V1594G | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); catalogued as COSV63683485; called by muse, mutect2, varscan2
- SARDH | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64096121, COSV64096588; called by muse, mutect2, varscan2
- SDR9C7 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV53289346; called by muse, mutect2, varscan2
- SEC24B | c.1394C>G p.T465R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV54498833; called by muse, mutect2, varscan2
- SEMA4C | c.2351C>G p.S784* | Nonsense Mutation (SNP) | VAF 39/116 reads (34%) | catalogued as COSV59690575; called by muse, mutect2, varscan2
- SEMA5B | c.2608G>C p.E870Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs754750748, COSV52096964, COSV99533167; called by muse, mutect2, varscan2
- SI | c.5294G>T p.S1765I | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated (0.14); PolyPhen benign (0.14); catalogued as COSV52276953; called by muse, mutect2, varscan2
- SINHCAF | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV61797282; called by muse, mutect2, varscan2
- SIPA1L2 | c.2333A>T p.D778V | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99479917; called by muse, mutect2, varscan2
- SIPA1L2 | c.2332G>T p.D778Y | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99479921; called by muse, mutect2, varscan2
- SLC25A48 | c.469G>T p.A157S (on ENST00000650267; = p.A103S on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.369); catalogued as COSV50848814; called by muse, mutect2
- SLC4A8 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60651664; called by muse, mutect2, varscan2
- SLC6A17 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV58992933; called by muse, mutect2, varscan2
- SLC6A19 | c.1717T>C p.S573P | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV57251103; called by muse, mutect2, varscan2
- SPEF2 | c.2885A>C p.K962T | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61547898; called by muse, mutect2, varscan2
- SPIN4 | c.157A>T p.N53Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV58737976; called by muse, mutect2, varscan2
- SPTA1 | c.4402A>T p.K1468* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as COSV63752532; called by muse, mutect2, varscan2
- SPTA1 | c.1004C>A p.P335H | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV63752534, COSV63759254; called by muse, mutect2, varscan2
- ST6GAL2 | c.1558C>A p.P520T | Missense Mutation (SNP) | VAF 33/95 reads (35%) | PolyPhen benign (0.021); catalogued as COSV62416518; called by muse, mutect2, varscan2
- STIM2 | c.568C>G p.H190D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.869); catalogued as COSV52838658; called by muse, mutect2, varscan2
- SUSD3 | c.558-2A>T p.X186_splice | Splice Site (SNP) | VAF 20/51 reads (39%) | catalogued as COSV64937206; called by muse, mutect2, varscan2
- SYNE1 | c.5563G>T p.E1855* (on ENST00000367255 / NM_182961.4; = p.E1862* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV54972400; called by muse, mutect2, varscan2
- SYTL4 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99343438; called by muse, mutect2, varscan2
- TAAR6 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV51583324, COSV51583460; called by muse, mutect2, varscan2
- TBCK | c.2476G>C p.G826R (on ENST00000273980 / NM_001163436.4; = p.G763R on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV56755240, COSV99912537; called by muse, mutect2, varscan2
- TENM4 | c.3821G>A p.S1274N | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV53626121; called by muse, mutect2, varscan2
- TGFB1I1 | c.185C>A p.T62K (on ENST00000394863 / NM_001042454.3; = p.T45K on NM_015927.4) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.925); catalogued as COSV62357871; called by muse, mutect2, varscan2
- TIE1 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs550355457, COSV65249588; called by muse, mutect2, varscan2
- TMC5 | c.2482C>T p.R828W (on ENST00000396229 / NM_001105248.1; = p.R582W on NM_024780.5) | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1313580380, COSV54903714; called by muse, mutect2, varscan2
- TMEM168 | c.787A>G p.R263G | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57180538; called by muse, mutect2, varscan2
- TMEM204 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs774099296, COSV54152563; called by muse, mutect2, varscan2
- TOB2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV59500944; called by muse, mutect2, varscan2
- TOX3 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV54866372; called by muse, mutect2, varscan2
- TPH2 | c.1064C>A p.A355D | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV61591842; called by muse, mutect2, varscan2
- TRIM37 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs1391941072, COSV51883544; called by muse, mutect2
- TRIO | c.1053G>T p.K351N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60083080; called by muse, mutect2, varscan2
- TRPC4 | c.2867G>A p.S956N (on ENST00000379705 / NM_016179.4; = p.S961N on NM_003306.3) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV58999077, COSV59014601; called by muse, mutect2, varscan2
- TTN | c.50041G>C p.V16681L (on ENST00000591111; = p.V9257L on NM_003319.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | PolyPhen possibly damaging (0.716); catalogued as COSV60033728; called by muse, mutect2, varscan2
- UBAP2L | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV55172167; called by muse, mutect2, varscan2
- UGDH | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57097646; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1880T>G p.F627C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV54437016; called by muse, mutect2, varscan2
- UNC5D | c.2417T>A p.I806N | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV54791523; called by muse, mutect2
- USP24 | c.4034G>A p.R1345Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs368254067, COSV99601139; called by muse, mutect2, varscan2
- WNT9A | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.5); catalogued as COSV55294318, COSV55294393; called by muse, mutect2, varscan2
- XRN1 | c.770A>G p.Y257C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53811331; called by muse, mutect2, varscan2
- XYLT1 | c.2362G>A p.V788I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.041); catalogued as rs201348549; called by muse, mutect2, varscan2
- ZFP14 | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs370356503; called by muse, mutect2, varscan2
- ZFP57 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs1402953555, COSV65306061; called by muse, mutect2, varscan2
- ZFPM2 | c.2530A>T p.T844S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV65873459; called by muse, mutect2
- ZMAT1 | c.700A>T p.R234* | Nonsense Mutation (SNP) | VAF 28/100 reads (28%) | catalogued as COSV65658430; called by muse, mutect2, varscan2
- ZNF160 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61999591; called by muse, mutect2, varscan2
- ZNF182 | c.617A>G p.Y206C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1449506187, COSV59357127; called by muse, mutect2, varscan2
- ZNF212 | c.1140C>G p.C380W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.907); catalogued as COSV60025048; called by mutect2, varscan2
- ZNF222 | c.419C>G p.S140* | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | catalogued as COSV51826610; called by muse, mutect2, varscan2
- ZNF256 | c.1160C>A p.S387Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV56597334; called by muse, mutect2, varscan2
- ZNF534 | c.238T>C p.W80R (on ENST00000332323 / NM_001143939.3; = p.W67R on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV56516681; called by muse, mutect2, varscan2
- ZNF581 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | catalogued as rs375452466; called by muse, mutect2, varscan2
- ZNF606 | c.1172C>G p.T391R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV58705848; called by muse, mutect2, varscan2
- ZNF678 | c.1085C>G p.S362* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as rs756269558, COSV59382587; called by muse, mutect2, varscan2
- ZNF98 | c.384C>A p.S128R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV63336261; called by muse, mutect2, varscan2
- ZNF99 | c.1289G>A p.C430Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68055648; called by muse, mutect2, varscan2
- ZP4 | c.604A>G p.N202D | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV63911846; called by muse, mutect2, varscan2
- ZP4 | c.451A>G p.R151G | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178561675, COSV63911849; called by muse, mutect2, varscan2
- ZXDB | c.1653C>G p.I551M | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as COSV100886086; called by muse, mutect2, varscan2
- ABCC11 | c.1981del p.L661Cfs*29 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- ABHD12B | c.335+1del | Frame Shift Del (DEL) | VAF 46/121 reads (38%) | called by mutect2, pindel, varscan2
- ASTN1 | c.1991G>C p.C664S | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ATP6V1E2 | c.479dup p.K161Efs*8 | Frame Shift Ins (INS) | VAF 22/115 reads (19%) | called by mutect2, pindel, varscan2
- BMPER | c.360dup p.W121Mfs*6 | Frame Shift Ins (INS) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- EGFR | c.3249del p.D1083Efs*11 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- FABP9 | c.340dup p.M114Nfs*6 | Frame Shift Ins (INS) | VAF 7/19 reads (37%) | called by mutect2, pindel, varscan2
- FRG2C | c.312G>C p.K104N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.075); called by muse, mutect2
- GUCY2F | c.2825del p.P942Qfs*17 | Frame Shift Del (DEL) | VAF 19/126 reads (15%) | called by mutect2, pindel, varscan2
- HERC2 | c.11107C>G p.R3703G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- IFT52 | c.570_577dup p.L193Pfs*58 | Frame Shift Ins (INS) | VAF 9/45 reads (20%) | called by mutect2, varscan2
- NLGN4X | c.1119dup p.G374Rfs*13 | Frame Shift Ins (INS) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- NRCAM | c.1828del p.D610Tfs*44 (on ENST00000379028 / NM_001371124.1; = p.D604Tfs*34 on NM_005010.4 and 21 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- PLPPR4 | c.1222del p.E408Rfs*18 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- POSTN | c.1513del p.Q505Kfs*17 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PRAMEF19 | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- STARD8 | c.1192del p.A398Hfs*61 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- TMEM161B | c.1409del p.L470Pfs*15 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- TRBV3-1 | c.123A>C p.K41N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTC31 | c.638del p.P213Hfs*46 | Frame Shift Del (DEL) | VAF 31/85 reads (36%) | called by mutect2, pindel, varscan2
- ZNF84 | c.1181A>C p.Q394P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ABCC10 | c.948G>C p.G316= (on ENST00000372530 / NM_001198934.2; = p.G273= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV55087202; called by muse, mutect2, varscan2
- ACAD10 | c.1839G>T p.P613= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100564231, COSV58156390; called by muse, mutect2, varscan2
- ALDH1L2 | c.72G>A p.K24= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV51555580; called by muse, mutect2, varscan2
- ALPI | c.1110G>A p.L370= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV55014507; called by muse, mutect2
- ANTKMT | c.390C>T p.R130= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV53496147; called by muse, mutect2, varscan2
- ARHGAP15 | c.1089T>A p.P363= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV54493958; called by muse, mutect2, varscan2
- ARHGEF37 | c.1789C>T p.L597= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV61368663; called by muse, mutect2, varscan2
- ARL1 | c.408C>T p.S136= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV55370287; called by muse, mutect2, varscan2
- ASPM | c.4294A>C p.R1432= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV54129278; called by muse, mutect2, varscan2
- ATG5 | c.459C>T p.L153= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV58347742; called by muse, mutect2, varscan2
- B4GALNT2 | c.1053C>A p.T351= | Silent (SNP) | VAF 60/203 reads (30%) | catalogued as COSV100302316, COSV55925934; called by muse, mutect2, varscan2
- CACNG6 | c.459C>A p.A153= | Silent (SNP) | VAF 116/250 reads (46%) | catalogued as COSV53166556; called by muse, mutect2, varscan2
- CD200R1L | c.717G>T p.L239= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV68004203; called by muse, mutect2, varscan2
- CFH | c.3180G>T p.V1060= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV66408076; called by muse, mutect2, varscan2
- CLP1 | c.972G>A p.V324= | Silent (SNP) | VAF 36/196 reads (18%) | catalogued as rs779116291, COSV57054402; called by muse, mutect2, varscan2
- CROCC | c.342C>T p.V114= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV65011868; called by muse, mutect2, varscan2
- CWC27 | c.1338C>A p.I446= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV66885380; called by mutect2, varscan2
- DEPDC5 | c.2358G>T p.T786= (on ENST00000400246; = p.T855= on NM_014662.5) | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV56696798, COSV56699868; called by muse, mutect2, varscan2
- DLGAP2 | c.2829G>A p.Q943= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs1344567996, COSV70097784; called by muse, mutect2, varscan2
- DOCK7 | c.4947C>T p.L1649= (on ENST00000635253 / NM_001367561.1; = p.L1618= on NM_033407.3) | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs892631582, COSV52004106; called by muse, mutect2
- EHD3 | c.1293A>T p.G431= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV59030372; called by muse, mutect2, varscan2
- EPHA8 | c.2805G>T p.V935= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV51267706; called by muse, mutect2, varscan2
- ETS2 | c.907C>T p.L303= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV62872877; called by muse, mutect2, varscan2
- F13B | c.1530G>A p.V510= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV66373690, COSV66375218; called by muse, mutect2, varscan2
- FAM47B | c.1570C>A p.R524= | Silent (SNP) | VAF 41/76 reads (54%) | catalogued as COSV61452687, COSV61453630; called by muse, mutect2, varscan2
- FAM83B | c.2175C>G p.T725= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV100174538, COSV100174635, COSV60921740; called by muse, mutect2, varscan2
- FANCF | c.558C>T p.A186= | Silent (SNP) | VAF 55/97 reads (57%) | catalogued as rs1198247121, COSV59416177; called by muse, mutect2, varscan2
- FBXO41 | c.1836C>G p.T612= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs1324480392, COSV54584155; called by muse, mutect2, varscan2
- FLNC | c.6633C>G p.T2211= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV57955367; called by muse, mutect2
- GABBR2 | c.1551A>G p.P517= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1181237592, COSV52302367; called by muse, mutect2, varscan2
- GABRQ | c.621G>T p.T207= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV64781851; called by muse, mutect2, varscan2
- GPR182 | c.153C>A p.T51= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV55626109; called by muse, mutect2, varscan2
- GREB1 | c.3582C>G p.P1194= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV52186344; called by muse, mutect2, varscan2
- HOXD12 | c.789G>A p.R263= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs766859471, COSV101184362; called by muse, mutect2, varscan2
- IFI16 | c.417C>A p.P139= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV55533574; called by muse, mutect2, varscan2
- IFNA13 | c.288T>C p.D96= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV101489531; called by muse, mutect2, varscan2
- INSYN1 | c.852C>A p.A284= | Silent (SNP) | VAF 65/171 reads (38%) | catalogued as COSV65837369; called by muse, mutect2, varscan2
- IQSEC2 | c.3129G>A p.G1043= (on ENST00000642864 / NM_001111125.3; = p.G838= on NM_015075.2) | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV64725219; called by muse, mutect2, varscan2
- IRX2 | c.324C>T p.Y108= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV57411050; called by muse, mutect2, varscan2
- KCNH7 | c.2745T>C p.D915= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV59795660; called by muse, mutect2, varscan2
- LGALS14 | c.351G>T p.P117= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV62372470, COSV62372550; called by muse, mutect2, varscan2
- LRRIQ1 | c.312A>G p.E104= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV67812975; called by muse, mutect2, varscan2
- LYPD2 | c.120C>A p.I40= | Silent (SNP) | VAF 23/181 reads (13%) | catalogued as COSV63649328; called by muse, mutect2, varscan2
- MAMDC2 | c.1443T>C p.C481= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV65852378; called by muse, mutect2, varscan2
- MCF2L2 | c.1740G>T p.R580= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV61052942; called by muse, mutect2, varscan2
- MPPED1 | c.300G>T p.S100= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as COSV61987490, COSV61987497; called by muse, mutect2, varscan2
- MUC16 | c.39126C>A p.V13042= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV67463324; called by muse, mutect2, varscan2
- MYH11 | c.948C>T p.P316= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV55552039, COSV55572307; called by muse, mutect2, varscan2
- MYOM1 | c.5031C>A p.S1677= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV55291107; called by muse, mutect2, varscan2
- NRXN2 | c.2868G>T p.L956= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV55452549; called by muse, mutect2, varscan2
- OR10G2 | c.465C>A p.V155= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV73390297, COSV73390361; called by muse, mutect2, varscan2
- OR13C8 | c.552C>A p.I184= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV58611065; called by muse, mutect2, varscan2
- OR4A47 | c.558C>T p.V186= | Silent (SNP) | VAF 24/163 reads (15%) | catalogued as COSV71444918, COSV71445263; called by muse, mutect2, varscan2
- OR51V1 | c.153G>T p.V51= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV58315014; called by muse, mutect2, varscan2
- OR5A1 | c.627C>T p.V209= | Silent (SNP) | VAF 37/185 reads (20%) | catalogued as rs777380839, COSV57375703, COSV57377939, COSV57378985; called by muse, mutect2, varscan2
- OR6Q1 | c.660G>T p.V220= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV56932954; called by muse, mutect2, varscan2
- PASD1 | c.1428C>A p.A476= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV64855129; called by muse, mutect2, varscan2
- PCDHGB5 | c.1278G>T p.P426= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV53941663; called by muse, mutect2, varscan2
- PDIA5 | c.846C>T p.T282= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs778671917, COSV60248959; called by muse, mutect2, varscan2
- PI15 | c.354G>A p.L118= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV52641099; called by muse, mutect2, varscan2
- PIGW | c.1279C>T p.L427= | Silent (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- PIWIL1 | c.1743C>A p.T581= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV55344708; called by muse, mutect2, varscan2
- PLG | c.807T>A p.S269= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV51982657; called by muse, mutect2, varscan2
- PLXNA3 | c.5508G>A p.K1836= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV63754001; called by muse, mutect2, varscan2
- PPP2R3A | c.1650C>G p.T550= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV53863366; called by muse, mutect2, varscan2
- PRPF19 | c.1452G>C p.G484= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV57127824; called by muse, mutect2, varscan2
- PRPF19 | c.882C>T p.P294= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV57127832; called by muse, mutect2, varscan2
- PRUNE2 | c.4566T>A p.L1522= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV65041186, COSV65049771; called by muse, mutect2, varscan2
- PSD | c.783C>T p.P261= | Silent (SNP) | VAF 29/43 reads (67%) | catalogued as rs763589602, COSV50045442; called by muse, mutect2, varscan2
- PTGIR | c.888C>A p.R296= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV52191996; called by muse, mutect2, varscan2
- PTGS1 | c.1680G>T p.T560= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs199581775, COSV56291274; called by muse, mutect2, varscan2
- RAP2A | c.237C>T p.I79= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs755647629, COSV55354985; called by muse, mutect2, varscan2
- RAVER1 | c.402G>A p.L134= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV50328999; called by muse, mutect2
- RRM2 | c.219G>A p.L73= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV58816670; called by muse, mutect2, varscan2
- SLC27A5 | c.564G>C p.L188= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV54019383; called by muse, mutect2, varscan2
- SLC39A12 | c.2040G>T p.L680= (on ENST00000377369 / NM_001145195.2; = p.L643= on NM_152725.3) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV66197816; called by muse, mutect2, varscan2
- SLC45A2 | c.1524G>C p.V508= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV56871549; called by muse, mutect2, varscan2
- SLC9A7 | c.72G>A p.L24= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1556295119, COSV60379868; called by muse, mutect2, varscan2
- SLITRK1 | c.69T>A p.V23= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as COSV65675410; called by muse, mutect2, varscan2
- SOHLH1 | c.561C>A p.S187= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV53681492; called by muse, mutect2, varscan2
- SYTL4 | c.210G>T p.L70= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV99343448; called by muse, mutect2, varscan2
- TEX44 | c.567C>T p.T189= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as rs1217278391, COSV58354918; called by muse, mutect2, varscan2
- TGIF2 | c.489A>G p.T163= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV65836432; called by muse, mutect2, varscan2
- THRA | c.876G>T p.L292= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV52842879; called by muse, mutect2, varscan2
- TIMP1 | c.258C>A p.T86= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV54483012; called by muse, mutect2, varscan2
- TKFC | c.768G>A p.V256= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV67523588; called by muse, mutect2, varscan2
- TPR | c.117G>A p.L39= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as rs1402738893, COSV55216655; called by muse, mutect2, varscan2
- TRBV27 | c.289C>T p.L97= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- TRPC3 | c.1278G>A p.V426= (on ENST00000379645 / NM_001366479.2; = p.V353= on NM_003305.2) | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV53373106, COSV53375091; called by muse, mutect2, varscan2
- TSHZ2 | c.756C>A p.P252= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV61588575; called by muse, mutect2, varscan2
- UNC5A | c.552C>A p.L184= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV56167557; called by muse, mutect2, varscan2
- UPP2 | c.360C>A p.S120= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV50046903; called by muse, mutect2, varscan2
- VAMP7 | c.81G>A p.E27= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV52901679; called by muse, mutect2, varscan2
- ZDBF2 | c.5536C>T p.L1846= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs763067950, COSV65625495; called by muse, mutect2, varscan2
- ZFP64 | c.1767G>C p.T589= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV53798690; called by muse, mutect2, varscan2
- ZNF536 | c.1431C>A p.A477= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV62833377; called by muse, mutect2
- ZNF536 | c.3651C>A p.P1217= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs201688634, COSV100835119, COSV62822661; called by muse, mutect2, varscan2
- ZNF835 | c.42G>A p.L14= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV73379418; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73820779 C>A | 3'Flank (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2
- AL353804.6 | chrX:73826352 G>A | 3'Flank (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851161 A>T | 3'Flank (SNP) | VAF 60/236 reads (25%) | called by muse, varscan2
- ENSA | c.183+109A>G | Intron (SNP) | VAF 48/243 reads (20%) | catalogued as COSV99651464; called by muse, mutect2, varscan2
- MLPH | c.*1C>T | 3'UTR (SNP) | VAF 23/51 reads (45%) | catalogued as rs139145016; called by muse, mutect2, varscan2
- WASF4P | n.342C>G | RNA (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
